Gene-level copy-number profile of tumor specimen BLGSP-71-06-00098-01B from CGCI case BLGSP-71-06-00098, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 8.6 years (3,134 days).
Specimen BLGSP-71-06-00098-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 76eaaf94-7e4c-4926-a08b-335f6ec35ab7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00098-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/901292e9-868c-429e-9565-2a85c4a108fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 130; copy number 1: 321; copy number 2: 56,333; copy number 3: 1,494; copy number 4: 71; copy number 5: 6; copy number 6: 6; copy number 7: 4; copy number 8: 6; copy number 9: 1; copy number 12: 5; copy number 14: 1; copy number 26: 1; copy number 28: 1.

Homozygous deletions (total copy number 0; autosomes only): 130 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:57,014,285–57,020,273, 1 gene: SLC29A4P1.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–3) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–3): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,654,890–87,655,243, 1 gene, copy number 7: RPS14P5.
- chr7:56,991,888–57,009,149, 1 gene, copy number 6: TNRC18P3.
- chr7:63,632,608–63,636,617, 1 gene, copy number 26: AC006015.1.
- chr8:8,088,941–8,089,089, 1 gene, copy number 28: MIR548I3.
- chr8:8,116,745–8,116,949, 1 gene, copy number 5: SNRPCP17.
- chr9:64,637,845–64,652,556, 1 gene, copy number 6: AL445665.1.
- chr9:64,817,870–64,836,341, 1 gene, copy number 5: AL359955.1.
- chr9:66,082,350–66,179,474, 4 genes, copy number 5 (within-gene range 4–5): SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr9:66,721,158–66,745,929, 3 genes, copy number 12: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr14:18,333,726–18,596,310, 5 genes, copy number 6–14 (within-gene range 3–14): CR383658.1, CR383658.2, BNIP3P6, CR383656.10, CR383656.7.
- chr14:18,889,084–19,055,551, 7 genes, copy number 6–12: NEK2P1, NF1P7, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4.
- chr21:13,095,305–13,120,807, 2 genes, copy number 8: ZNF355P, AJ239321.1.
- chr21:44,107,373–44,210,114, 3 genes, copy number 6–8 (within-gene range 2–8): PWP2, GATD3A, LINC01678.

Autosomal genes at a single copy (total copy number 1): 321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
